Somatic mutation profile of tumor specimen 0DKAKX from CCDI case PBBYAE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.2 years (1,186 days).
Specimen 0DKAKX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e448b44-9602-4caa-bea1-4f9c7b311cbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKAKM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67784254-cbc7-4371-878a-cac718ef2142

The open-access MAF lists 19 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, 5'UTR 3, Intron 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 153/1198 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTK2 | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 56/1244 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as rs879163959; called by muse, mutect2
- SLC4A2 | c.3275C>T p.T1092M | Missense Mutation (SNP) | VAF 200/630 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs370805035; called by muse, mutect2, varscan2
- TRIM36 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 58/1505 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs757552514, COSV56693152; called by muse, mutect2
- TUT1 | c.1468C>T p.P490S | Missense Mutation (SNP) | VAF 77/697 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.045); catalogued as rs1394046491; called by muse, mutect2, varscan2
- ZMAT2 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 70/1439 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51226872; called by muse, mutect2
- DCAF13 | c.71-1G>T p.X24_splice | Splice Site (SNP) | VAF 99/571 reads (17%) | called by muse, mutect2, varscan2
- OR14I1 | c.218_219del p.S73Cfs*5 | Frame Shift Del (DEL) | VAF 86/830 reads (10%) | called by mutect2, varscan2
- SLITRK2 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 507/1197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHERP | c.2742G>A p.E914= | Silent (SNP) | VAF 169/551 reads (31%) | catalogued as rs756725468; called by muse, mutect2, varscan2
- HIBADH | c.210G>A p.V70= | Silent (SNP) | VAF 653/1468 reads (44%) | called by muse, mutect2, varscan2
- LILRA4 | c.1251C>T p.V417= | Silent (SNP) | VAF 256/2101 reads (12%) | called by muse, varscan2
- MAN2B2 | c.2514C>T p.S838= | Silent (SNP) | VAF 404/923 reads (44%) | catalogued as rs776475620, COSV99577160; called by muse, mutect2, varscan2
- TSPAN14 | c.561C>T p.C187= | Silent (SNP) | VAF 531/1245 reads (43%) | catalogued as rs1234629540; called by muse, mutect2, varscan2
- EGLN1 | c.1149-41G>A | Intron (SNP) | VAF 262/648 reads (40%) | catalogued as rs750082301; called by muse, mutect2, varscan2
- KCNH4 | c.-80C>A | 5'UTR (SNP) | VAF 28/46 reads (61%) | catalogued as rs1039196287; called by muse, mutect2, varscan2
- OR9A2 | c.-46T>C | 5'UTR (SNP) | VAF 28/842 reads (3%) | called by muse, mutect2
- PIH1D1 | c.-38G>A | 5'UTR (SNP) | VAF 38/444 reads (9%) | called by muse, mutect2
- Z96074.1 | n.151+3149C>T | Intron (SNP) | VAF 38/1363 reads (3%) | called by muse, mutect2
